Somatic mutation profile of tumor specimen TCGA-AP-A1E4-01A (aliquot TCGA-AP-A1E4-01A-12D-A135-09) from TCGA case TCGA-AP-A1E4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.2 years (19,814 days).
Specimen TCGA-AP-A1E4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c73e2368-5387-4db5-b233-75eac5384c1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A1E4-10A (Blood Derived Normal), aliquot TCGA-AP-A1E4-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6bec0be4-4f6d-48b2-96ff-1f0741972073

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 16, Silent 9, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 60/99 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- ADCY2 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57866093; called by muse, mutect2, varscan2
- C1orf116 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs201485765, COSV100847888, COSV100847986; called by muse, mutect2, varscan2
- CCL2 | c.87T>A p.N29K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs1335527383, COSV99861500; called by muse, mutect2, varscan2
- CSTF2 | c.128T>C p.V43A | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV100802913; called by muse, mutect2, varscan2
- DTX4 | c.1356G>A p.M452I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99915095; called by muse, mutect2, varscan2
- FOXA2 | c.631C>T p.L211F (on ENST00000377115 / NM_153675.3; = p.L217F on NM_021784.5) | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101008268; called by muse, mutect2, varscan2
- FUT5 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99398581; called by muse, mutect2, varscan2
- GNPTAB | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100171761, COSV54776815; called by muse, mutect2, varscan2
- PANX3 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369951022; called by muse, mutect2, varscan2
- RHBDF2 | c.1748G>A p.S583N | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1430985507, COSV99166185; called by muse, mutect2, varscan2
- SAXO2 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100255594, COSV59753971; called by muse, mutect2, varscan2
- TRIO | c.5092G>T p.V1698L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100710014; called by muse, mutect2, varscan2
- TSSK1B | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV101180976; called by muse, mutect2, varscan2
- ZSCAN4 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99989804; called by muse, mutect2, varscan2
- DACH1 | c.2150_2153del p.D717Vfs*5 (on ENST00000619232 / NM_001366712.1; = p.D463Vfs*5 on NM_004392.6) | Frame Shift Del (DEL) | VAF 49/123 reads (40%) | called by mutect2, pindel, varscan2
- IGHA1 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- UCP3 | c.231dup p.Y78Lfs*23 | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- HECTD4 | c.11592C>T p.C3864= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs574699719, COSV66387458; called by muse, mutect2, varscan2
- KRT33A | c.60C>T p.P20= | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as rs1450869459, COSV99144783; called by muse, mutect2, varscan2
- LIAS | c.24A>G p.A8= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as rs750426614, COSV99787589; called by muse, mutect2, varscan2
- LRRC3 | c.213C>T p.L71= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as rs750321909, COSV52400670; called by muse, mutect2, varscan2
- LRRC3B | c.570C>T p.N190= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs375239096; called by muse, mutect2, varscan2
- MMP17 | c.1761G>A p.P587= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100861873; called by muse, mutect2, varscan2
- MRPL55 | c.129G>A p.V43= | Silent (SNP) | VAF 62/234 reads (26%) | catalogued as COSV99686754; called by muse, mutect2, varscan2
- RBM3 | c.24C>G p.L8= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs782613569, COSV100618686; called by muse, mutect2, varscan2
- TMEM86A | c.184C>T p.L62= | Silent (SNP) | VAF 81/158 reads (51%) | catalogued as COSV99773562; called by muse, mutect2, varscan2
